Gene-level copy-number profile of tumor specimen ALCH-B3GE-TTP1-A from ALCHEMIST case ALCH-B3GE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.2 years (24,175 days).
Specimen ALCH-B3GE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dd656b2a-a311-44ed-85e1-9388e8e13ee2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3GE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/d3597d5c-bf2c-4fc6-a74d-0306f42079cb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 20,996; copy number 2: 32,750; copy number 3: 4,606; copy number 4: 436; copy number 5: 99; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:56,805,336–56,848,800, 2 genes: CICP28, AC118758.2.
- chr7:131,661,952–131,665,858, 2 genes: EEF1B2P6, AC093106.1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr8:43,539,137–43,544,057, 3 genes: AC134698.5, CYP4F44P, AC134698.2.
- chr13:52,488,993–52,587,095, 2 genes: AL137058.1, AL137058.3.
- chr17:62,679,403–62,684,010, 2 genes (within-gene range 0–2): AC080038.3, RNU6-446P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 100 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:56,940,341–56,944,353, 1 gene, copy number 11: AC069152.1.
- chr20:62,122,461–63,843,915, 99 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,344. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
